Somatic mutation profile of tumor specimen TCGA-AG-4021-01A (aliquot TCGA-AG-4021-01A-01D-1733-10) from TCGA case TCGA-AG-4021, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 84.9 years (31,015 days).
Specimen TCGA-AG-4021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deab2fea-562e-45c3-921d-70915ee4f89a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-4021-10A (Blood Derived Normal), aliquot TCGA-AG-4021-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f94f402-ee00-4c7c-bd7e-999b34cf06ce

The open-access MAF lists 146 somatic variants for this specimen: 112 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 30, Nonsense Mutation 5, Intron 3, Frame Shift Ins 3, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>C p.Y205S | Missense Mutation (SNP) | VAF 39/64 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1445T>A p.I482N (on ENST00000404938 / NM_001163941.2; = p.I37N on NM_178559.6) | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51705898; called by muse, mutect2, varscan2
- ADGRB1 | c.3481C>T p.R1161C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs945515473, COSV60093655; called by muse, mutect2, varscan2
- AMOTL1 | c.2762T>A p.L921Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58565612; called by muse, mutect2, varscan2
- ARHGAP6 | c.2294G>C p.R765T (on ENST00000337414 / NM_013427.3; = p.R562T on NM_013423.3) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV100273485; called by muse, mutect2
- ARHGEF6 | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51688726; called by muse, mutect2, varscan2
- ASPM | c.6242A>G p.K2081R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV54126867, COSV99660713; called by muse, mutect2, varscan2
- ATP13A3 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99757533; called by muse, mutect2, varscan2
- ATRNL1 | c.744C>A p.Y248* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV61800053; called by muse, mutect2, varscan2
- AXIN2 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61056432; called by muse, mutect2, varscan2
- BICRA | c.3908G>A p.R1303Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1056687911, COSV67604224; called by muse, mutect2, varscan2
- BRD4 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54583822, COSV99651744; called by muse, mutect2, varscan2
- BRWD3 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777162950, COSV64745464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D3 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749577299, COSV55517702; called by muse, mutect2, varscan2
- CDH16 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs375247196; called by muse, mutect2, varscan2
- CLEC16A | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs201362914, COSV68498617; called by muse, mutect2, varscan2
- CLTCL1 | c.4783G>C p.A1595P (on ENST00000427926 / NM_007098.4; = p.A1538P on NM_001835.4) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV53205445; called by muse, mutect2, varscan2
- CPAMD8 | c.2930T>C p.V977A (on ENST00000651564; = p.V930A on NM_015692.5) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV71596212; called by muse, mutect2, varscan2
- DCHS1 | c.6518G>A p.R2173Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55032676; called by muse, mutect2, varscan2
- DCLK1 | c.782A>C p.E261A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99712656; called by muse, mutect2, varscan2
- DCUN1D2 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1393797005, COSV60260942, COSV60261753; called by muse, mutect2, varscan2
- DDX53 | c.529_530insT p.N177Ifs*14 | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | catalogued as COSV60068663; called by mutect2, pindel, varscan2
- DMBT1 | c.7513C>T p.R2505* (on ENST00000338354 / NM_001377530.1; = p.R1748* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 52/124 reads (42%) | catalogued as COSV57538121, COSV57569406; called by muse, mutect2, varscan2
- DNAI1 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs376252276, CM152113, CS066632, COSV99647088; called by muse, mutect2, varscan2
- DOCK2 | c.554A>T p.H185L | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV56948756; called by muse, mutect2, varscan2
- DOCK7 | c.5525A>C p.Y1842S (on ENST00000635253 / NM_001367561.1; = p.Y1811S on NM_033407.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52024313, COSV99225657; called by muse, mutect2, varscan2
- DOCK7 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51999823; called by muse, mutect2, varscan2
- DONSON | c.998G>C p.S333T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.076); catalogued as COSV51653753; called by muse, mutect2, varscan2
- DPY19L1 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774134203, COSV100204875, COSV60581429; called by muse, mutect2, varscan2
- EBPL | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV54431843; called by muse, mutect2, varscan2
- EP400 | c.7849C>T p.R2617C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs767424945, COSV57767160; called by muse, mutect2, varscan2
- EPHA7 | c.2766C>A p.F922L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as COSV65177385, COSV65179247; called by muse, mutect2, varscan2
- EPRS1 | c.2102A>G p.Y701C | Missense Mutation (SNP) | VAF 193/453 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as rs1338232644, COSV65097758; called by muse, varscan2
- FAM135A | c.2297G>C p.R766T (on ENST00000370479 / NM_001351599.1; = p.R553T on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV52049130; called by muse, mutect2, varscan2
- FAM83B | c.902G>A p.W301* | Nonsense Mutation (SNP) | VAF 341/406 reads (84%) | catalogued as COSV60920443; called by muse, mutect2, varscan2
- FLRT2 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs772274794, COSV58150502; called by muse, mutect2, varscan2
- GAS2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs767538779, COSV99535563; called by muse, mutect2, varscan2
- GPR161 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767649249, COSV54788671; called by muse, mutect2, varscan2
- GRIN2A | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778951185, COSV58035660; called by muse, mutect2, varscan2
- GRK7 | c.219C>G p.F73L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV53822036; called by mutect2, varscan2
- HCRTR2 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 216/275 reads (79%) | SIFT tolerated (0.56); PolyPhen benign (0.05); catalogued as COSV63794577; called by muse, mutect2, varscan2
- HIF3A | c.391G>T p.D131Y (on ENST00000377670 / NM_152795.4; = p.D62Y on NM_022462.4) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52196743; called by muse, mutect2, varscan2
- HTR2C | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52204658; called by muse, mutect2, varscan2
- INF2 | c.2672G>A p.R891Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.127); catalogued as rs777498088, COSV53031080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS8 | c.2555C>G p.A852G | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100569407; called by muse, mutect2, varscan2
- ITGA4 | c.430T>G p.C144G | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51998775; called by muse, mutect2, varscan2
- KCNB2 | c.249C>G p.N83K | Missense Mutation (SNP) | VAF 62/95 reads (65%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV101578951, COSV73048960; called by muse, mutect2, varscan2
- KIF2B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs754482684, COSV52128242; called by muse, mutect2, varscan2
- KRT26 | c.21del p.G8Dfs*78 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | catalogued as COSV56971153; called by mutect2, pindel, varscan2
- KRT35 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs577676650, COSV55842591, COSV99877733; called by muse, mutect2, varscan2
- LMO7 | c.3285G>T p.K1095N (on ENST00000357063; = p.K776N on NM_005358.5) | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58532170; called by muse, mutect2, varscan2
- MAPK12 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201816702, COSV53132470; called by muse, mutect2, varscan2
- MCM9 | c.1124C>G p.T375S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57647506; called by muse, mutect2, varscan2
- MED12L | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780300319, COSV56372883; called by muse, mutect2, varscan2
- METTL25 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV50258213; called by muse, mutect2, varscan2
- MSC | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57696401, COSV57696868; called by muse, mutect2
- MUC16 | c.30199G>T p.E10067* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV67453821, COSV67489990; called by muse, mutect2, varscan2
- MUC16 | c.25817G>A p.R8606H | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs182118027, COSV67443664; called by muse, mutect2, varscan2
- NISCH | c.2987G>A p.R996H | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs528293970, COSV61899034; called by muse, mutect2, varscan2
- NKTR | c.3374C>A p.T1125K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV51770380; called by muse, mutect2, varscan2
- NLRP12 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV60744876, COSV60744973; called by muse, mutect2, varscan2
- NOS1 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV57608943; called by muse, mutect2, varscan2
- NOS3 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1329785228, COSV52487518; called by muse, mutect2, varscan2
- NOX4 | c.300A>C p.K100N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54449396; called by muse, mutect2, varscan2
- NOX5 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs752341477, COSV52986357; called by muse, mutect2, varscan2
- NRP2 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs111369832, COSV99785388; called by muse, mutect2, varscan2
- NRXN2 | c.3734C>T p.P1245L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55450049; called by muse, mutect2, varscan2
- OR2M2 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1266385239, COSV62898471, COSV62899089; called by muse, mutect2, varscan2
- OR4C15 | c.602C>T p.A201V (on ENST00000314644; = p.A147V on NM_001001920.2) | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.959); catalogued as COSV100115561, COSV100116073, COSV58951716; called by muse, mutect2, varscan2
- PCDHA6 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs782678878, COSV65342966; called by muse, mutect2, varscan2
- PCDHB12 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.309); catalogued as COSV99507706; called by mutect2, varscan2
- PCDHGB3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs1393089776, COSV53907465; called by muse, mutect2, varscan2
- PCDHGB6 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs1427716409, COSV53917420; called by muse, mutect2, varscan2
- PHKA2 | c.3295T>A p.S1099T | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as COSV66052563, COSV66052949; called by muse, mutect2, varscan2
- PKHD1 | c.5990G>A p.R1997Q | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as rs1486620317, COSV61866452; called by muse, mutect2
- PLXNA1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs372267530; called by muse, mutect2, varscan2
- PLXND1 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779527122, COSV100140296; called by muse, mutect2, varscan2
- PRKDC | c.10814dup p.N3605Kfs*3 | Frame Shift Ins (INS) | VAF 204/360 reads (57%) | catalogued as rs1284489077; called by mutect2, varscan2
- RNF113B | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1167910497, COSV57434659; called by muse, mutect2
- RYR3 | c.7778C>T p.A2593V (on ENST00000389232; = p.A2594V on NM_001036.6) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs201466342; called by muse, mutect2, varscan2
- SCN3A | c.4678C>T p.R1560W | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1410775973, COSV99328175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA7 | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs1281301948, COSV59665213; called by muse, mutect2, varscan2
- SFN | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs532069878, COSV59433048; called by muse, mutect2, varscan2
- SH3BP4 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs756321673, COSV60643038; called by muse, mutect2, varscan2
- SH3KBP1 | c.1314G>T p.K438N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV65646468; called by muse, mutect2, varscan2
- SHCBP1L | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs757649009, COSV62353893; called by muse, mutect2, varscan2
- SHROOM2 | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs777124643, COSV66605384; called by muse, mutect2, varscan2
- SIX4 | c.1631T>C p.F544S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53668976; called by muse, mutect2, varscan2
- SLC19A1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs765709900, COSV60753620; called by muse, mutect2, varscan2
- SMC1A | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 93/145 reads (64%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV59128453; called by muse, mutect2, varscan2
- SOX17 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52025224; called by muse, mutect2
- SPAM1 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56141998; called by muse, mutect2, varscan2
- STARD8 | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV99367488; called by muse, mutect2, varscan2
- STX4 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100572989, COSV58268127; called by muse, mutect2, varscan2
- TECRL | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV101169292; called by muse, mutect2, varscan2
- TEP1 | c.6496C>T p.R2166W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs766453939, COSV52989806; called by muse, mutect2, varscan2
- TGFBR3 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762822366, COSV99283570; called by muse, mutect2, varscan2
- THSD7A | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs138073597; called by muse, mutect2, varscan2
- TLR10 | c.2256dup p.A753Sfs*9 | Frame Shift Ins (INS) | VAF 36/114 reads (32%) | catalogued as rs564674109; called by mutect2, varscan2
- TMEM260 | c.2071C>G p.L691V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV55097122; called by muse, mutect2, varscan2
- TMPRSS15 | c.2615G>C p.R872T | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53036744; called by muse, mutect2, varscan2
- TULP4 | c.3500C>A p.P1167H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65573646; called by muse, mutect2, varscan2
- XRCC5 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772117253, COSV67534917; called by muse, mutect2, varscan2
- ZNF407 | c.5533G>A p.V1845I | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs112538866; called by muse, mutect2, varscan2
- ZNF556 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs368319229; called by muse, mutect2, varscan2
- ZNF587 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 89/463 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100299629; called by muse, mutect2, varscan2
- ZNF878 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV72155904; called by muse, mutect2, varscan2
- BSN | c.6614C>T p.T2205I | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CTNND2 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- DDX55 | c.1434_1442delinsA p.D478Efs*7 | Frame Shift Del (DEL) | VAF 32/73 reads (44%) | called by pindel, varscan2*
- TTLL12 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2
- ABCA13 | c.195T>C p.C65= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV70026864; called by muse, mutect2, varscan2
- ABCA6 | c.3420C>T p.I1140= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99447458; called by muse, mutect2, varscan2
- ANK2 | c.2364C>T p.N788= | Silent (SNP) | VAF 72/103 reads (70%) | catalogued as rs769405364, COSV52152112; called by muse, mutect2, varscan2
- ATP4A | c.1413G>A p.S471= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV52866714; called by muse, mutect2, varscan2
- BAK1 | c.87G>A p.Q29= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100645834; called by muse, mutect2
- CARD11 | c.1371C>A p.I457= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV62754571, COSV62756389; called by muse, mutect2, varscan2
- CELA2A | c.285C>T p.S95= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as rs375040985; called by muse, mutect2, varscan2
- DCLRE1B | c.285C>T p.L95= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as rs547539348, COSV99871073; called by muse, mutect2, varscan2
- EIF4G1 | c.3294C>T p.S1098= (on ENST00000346169 / NM_198241.3; = p.S903= on NM_004953.5) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1273972150, COSV59989858; called by muse, mutect2, varscan2
- ELOA3 | c.804G>A p.S268= | Silent (SNP) | VAF 8/56 reads (14%) | called by mutect2, varscan2
- FAM110B | c.855G>A p.P285= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as rs1167379325, COSV100826277, COSV64063748; called by muse, mutect2, varscan2
- GAD2 | c.1581G>A p.S527= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs763555415, COSV52153305; called by muse, mutect2, varscan2
- GPAT2 | c.1206G>A p.E402= | Silent (SNP) | VAF 119/259 reads (46%) | catalogued as COSV64003250; called by muse, mutect2, varscan2
- GRM8 | c.1246C>T p.L416= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100280604, COSV58812890; called by muse, mutect2, varscan2
- KRT27 | c.624G>A p.L208= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV56971163; called by muse, mutect2, varscan2
- LDLRAP1 | c.894C>T p.S298= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs747886166, COSV65473274; called by muse, mutect2, varscan2
- LIMD1 | c.723G>A p.E241= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV56266369; called by muse, mutect2, varscan2
- MYO7B | c.2664C>T p.A888= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs368877066, COSV101268425; called by muse, mutect2, varscan2
- NUP205 | c.3714T>C p.A1238= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV53656544; called by muse, mutect2, varscan2
- OR4K1 | c.471G>A p.V157= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV53459280; called by muse, mutect2, varscan2
- OTOF | c.3711G>A p.S1237= (on ENST00000272371 / NM_194248.3; = p.S490= on NM_004802.4) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs141973547; called by muse, mutect2, varscan2
- PLXNB3 | c.1164G>A p.Q388= | Silent (SNP) | VAF 78/114 reads (68%) | catalogued as COSV62796165; called by muse, mutect2, varscan2
- SLC4A1 | c.1737C>T p.A579= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs773192966, COSV52259097; called by muse, mutect2, varscan2
- STAT5B | c.1491C>T p.A497= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs772239606, COSV53181266; called by muse, mutect2, varscan2
- STC1 | c.180G>A p.L60= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV51688064, COSV51689113; called by muse, mutect2
- TRIM15 | c.486C>T p.I162= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as rs1351659184, COSV64989178; called by muse, mutect2, varscan2
- TSSK1B | c.411C>A p.L137= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV66815065; called by muse, mutect2, varscan2
- USH2A | c.13980G>A p.P4660= | Silent (SNP) | VAF 59/134 reads (44%) | catalogued as rs201127899, COSV100240791; called by muse, mutect2, varscan2
- WDR76 | c.1815G>A p.R605= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV99776690; called by muse, mutect2, varscan2
- ZNF639 | c.324A>T p.V108= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs1435024272, COSV58382867; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1541C>T | Intron (SNP) | VAF 30/71 reads (42%) | catalogued as COSV63750947; called by muse, mutect2, varscan2
- CHCHD2P9 | n.32G>A | RNA (SNP) | VAF 27/66 reads (41%) | catalogued as rs373756242; called by muse, mutect2, varscan2
- P3H1 | c.2055+141C>T | Intron (SNP) | VAF 38/91 reads (42%) | catalogued as rs370150778, COSV52532411; called by muse, mutect2, varscan2
- VPS28 | c.549-59G>A | Intron (SNP) | VAF 18/68 reads (26%) | catalogued as rs782640000, COSV52871291; called by muse, mutect2, varscan2
